Somatic mutation profile of tumor specimen TCGA-B5-A0JU-01B (aliquot TCGA-B5-A0JU-01B-11D-A14G-09) from TCGA case TCGA-B5-A0JU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 57.9 years (21,159 days).
Specimen TCGA-B5-A0JU-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82053b63-b215-4ff3-8e54-cab490d6b964.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0JU-10A (Blood Derived Normal), aliquot TCGA-B5-A0JU-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b65d4049-1ba4-495e-b498-82bc16482f6d

The open-access MAF lists 533 somatic variants for this specimen: 374 protein-altering or splice-affecting, 143 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 240, Silent 143, Frame Shift Del 99, Frame Shift Ins 14, Nonsense Mutation 11, Intron 5, Splice Site 4, 5'Flank 4, RNA 4, In Frame Del 2, 3'Flank 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by mutect2, varscan2
- AGXT | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180177156, CM983926, COSV100280370; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ARSA | c.302dup p.L102Pfs*32 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs761606317; ClinVar: pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 46/85 reads (54%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CHD1 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554078349, COSV99399882; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 12/24 reads (50%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 21/42 reads (50%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 10/17 reads (59%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 16/32 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WFS1 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs387906930, CM015844, CM108446, COSV56990418; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV101330173; called by muse, mutect2, varscan2
- ABCB6 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99202508; called by muse, mutect2, varscan2
- ABL2 | c.1441T>C p.Y481H (on ENST00000502732 / NM_007314.4; = p.Y466H on NM_005158.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100772985; called by muse, mutect2, varscan2
- ACTG2 | c.85del p.R29Gfs*16 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | catalogued as rs751325833; called by mutect2, pindel, varscan2
- ACTR2 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53200219; called by muse, mutect2, varscan2
- ADAM23 | c.2237C>T p.S746L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs982795571, COSV52220908; called by muse, mutect2, varscan2
- ADAMTS9 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99900186; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2848dup p.H950Pfs*13 | Frame Shift Ins (INS) | VAF 7/15 reads (47%) | catalogued as rs1022557002; called by mutect2, varscan2
- ADCY10 | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV100897083; called by muse, mutect2, varscan2
- ADCY6 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100326897; called by muse, mutect2, varscan2
- ADGRL1 | c.2305G>A p.A769T (on ENST00000340736 / NM_001008701.3; = p.A764T on NM_014921.5) | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.48); PolyPhen benign (0.216); catalogued as COSV61564099; called by muse, mutect2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- AGO4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759153717, COSV64617690; called by muse, mutect2, varscan2
- AHSA1 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99376212; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 27/59 reads (46%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.4960A>G p.R1654G | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs757996597, COSV62339678; called by muse, mutect2, varscan2
- AL035461.3 | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs145778654; called by muse, mutect2, varscan2
- ALDH1L2 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99311305; called by muse, mutect2, varscan2
- AMELX | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs771933695, COSV61635437; called by muse, mutect2, varscan2
- AOC1 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1239324659, COSV100710985; called by muse, mutect2, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs759782104; called by mutect2, pindel, varscan2
- ARHGAP17 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99254037; called by muse, mutect2, varscan2
- ARHGAP6 | c.2677G>A p.A893T (on ENST00000337414 / NM_013427.3; = p.A690T on NM_013423.3) | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV100273558; called by muse, mutect2, varscan2
- ARID1A | c.3994C>T p.Q1332* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV61378539; called by muse, varscan2
- ASPSCR1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs558896726, COSV60727816; called by muse, mutect2, varscan2
- ASTN2 | c.3431G>A p.G1144E (on ENST00000313400 / NM_001365069.1; = p.G1093E on NM_014010.5) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs781306907, COSV99941687; called by muse, mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATG4B | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs756120336, COSV100728782; called by muse, mutect2, varscan2
- ATP2B3 | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99685809; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- BCHE | c.1027del p.T343Pfs*16 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as CM025285, COSV52257903; called by mutect2, pindel, varscan2
- BEST3 | c.45del p.F15Lfs*32 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs1184020574; called by mutect2, pindel, varscan2
- BMP1 | c.2779G>A p.G927S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147298430; called by muse, mutect2, varscan2
- BRD3 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100325529; called by muse, mutect2, varscan2
- BRINP1 | c.2126C>A p.P709H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV99776885; called by muse, mutect2
- BRINP3 | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100819444, COSV66529448; called by muse, mutect2, varscan2
- C11orf42 | c.584T>C p.F195S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99792491; called by muse, mutect2, varscan2
- C14orf93 | c.1424C>A p.P475H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV99401186; called by muse, mutect2, varscan2
- C1QL2 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99733354; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs1558068270; called by mutect2, pindel, varscan2
- C3orf52 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99332670; called by muse, mutect2, varscan2
- CACNA1D | c.28del p.M10Cfs*60 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as COSV55457798; called by mutect2*, pindel, varscan2*
- CASC3 | c.524A>C p.D175A | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99230018; called by muse, mutect2, varscan2
- CBLN2 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54050407; called by muse, mutect2, varscan2
- CCKBR | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747382508, COSV58098347, COSV58103191; called by muse, varscan2
- CD19 | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV100218262; called by muse, mutect2, varscan2
- CDT1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV99967369; called by muse, mutect2, varscan2
- CENPJ | c.3778C>G p.Q1260E | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV99694408; called by muse, mutect2, varscan2
- CEP164 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs766713516, COSV54046202; called by muse, mutect2, varscan2
- CERCAM | c.1430A>G p.Y477C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100864117; called by muse, mutect2, varscan2
- CES3 | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310044; called by muse, mutect2, varscan2
- CFAP221 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV99733133; called by muse, mutect2, varscan2
- CFAP47 | c.986C>A p.P329H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99935826; called by muse, mutect2, varscan2
- CGB7 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs752113515, COSV100655123; called by muse, mutect2, varscan2
- CHEK2 | c.1162C>T p.H388Y (on ENST00000382580 / NM_001005735.2; = p.H345Y on NM_007194.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs864622537, COSV100102488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHGA | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99381288; called by muse, mutect2, varscan2
- CHPT1 | c.485dup p.C163Lfs*31 | Frame Shift Ins (INS) | VAF 42/157 reads (27%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRNA4 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs142137599; ClinVar: uncertain significance; called by muse, mutect2
- CMTR1 | c.1721C>A p.P574H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as COSV100990938; called by muse, mutect2, varscan2
- COL14A1 | c.4493G>A p.G1498E | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920370; called by muse, mutect2, varscan2
- COL4A2 | c.4879A>G p.M1627V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100847480; called by muse, mutect2, varscan2
- COPS8 | c.204T>A p.N68K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as COSV100585473; called by muse, mutect2, varscan2
- CPT1B | c.2128G>A p.G710S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100376839; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs747248693; called by mutect2, varscan2
- CSDE1 | c.277_279del p.E93del | In Frame Del (DEL) | VAF 35/73 reads (48%) | catalogued as rs754657826; called by mutect2, pindel, varscan2
- CSMD1 | c.7834G>T p.G2612* (on ENST00000520002; = p.G2611* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100153571; called by muse, mutect2, varscan2
- CSMD3 | c.9395C>A p.T3132K (on ENST00000297405 / NM_001363185.1; = p.T2963K on NM_052900.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.606); catalogued as COSV52292760, COSV99847328; called by muse, mutect2, varscan2
- CTCF | c.143del p.G48Vfs*14 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as COSV50489849, COSV99864074; called by mutect2, pindel, varscan2
- CYB561A3 | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs778479865, COSV99582682; called by muse, mutect2, varscan2
- DBN1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs763518397, COSV52787940; called by muse, mutect2, varscan2
- DBR1 | c.1299A>T p.E433D | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99604632; called by muse, varscan2
- DCHS1 | c.2180G>A p.G727D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100202574; called by muse, mutect2, varscan2
- DCLRE1C | c.1820G>T p.S607I (on ENST00000378278 / NM_001350965.2; = p.S492I on NM_022487.4) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.312); catalogued as COSV100543192; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs766714372; called by mutect2, varscan2
- DEFB132 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV101212638, COSV66677442; called by muse, mutect2, varscan2
- DGKQ | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1174413023, COSV99298222; called by muse, mutect2, varscan2
- DIP2A | c.3574G>A p.A1192T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.448); catalogued as rs749572406, COSV100596325; called by muse, mutect2, varscan2
- DISP1 | c.3665G>A p.S1222N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV99452171; called by muse, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as rs745893364; called by mutect2, varscan2
- DNMBP | c.3908A>G p.D1303G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100144409; called by muse, mutect2, varscan2
- EIF2S3 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV53407720; called by muse, mutect2, varscan2
- ELK1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs766556938, COSV99902354; called by muse, mutect2, varscan2
- EMILIN1 | c.1353del p.L452Cfs*5 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as COSV53155402; called by mutect2, varscan2
- ENPP6 | c.1025G>A p.S342N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.116); catalogued as rs756931617, COSV99699136; called by muse, mutect2, varscan2
- ERICH5 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575526227, COSV59315550; called by muse, mutect2, varscan2
- ESCO1 | c.615dup p.R206Tfs*12 | Frame Shift Ins (INS) | VAF 16/59 reads (27%) | catalogued as rs1568106947; called by mutect2, pindel, varscan2
- ESCO2 | c.595del p.I199* | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs1563468940; called by mutect2, pindel, varscan2
- ESRRG | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV100753872; called by muse, mutect2, varscan2
- EVC | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs199904401; called by muse, mutect2, varscan2
- EVC2 | c.2798A>T p.E933V | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100186878; called by muse, mutect2, varscan2
- EVPL | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV56908567; called by muse, mutect2
- EXOC4 | c.2579G>T p.R860M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV99555679; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM189B | c.854del p.P285Lfs*36 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as COSV56944898; called by mutect2, pindel, varscan2
- FAM47C | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs138293293, COSV100792387, COSV100792939; called by muse, mutect2, varscan2
- FAN1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374131595; called by muse, mutect2, varscan2
- FASN | c.7343C>T p.A2448V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60759891; called by muse, mutect2, varscan2
- FBXO46 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.183); catalogued as rs751819786, COSV100480249, COSV100480409; called by muse, mutect2, varscan2
- FCHO1 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV99406475; called by mutect2, varscan2
- FCRL4 | c.1410G>T p.Q470H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); catalogued as rs1273793673, COSV99619174, COSV99620435; called by muse, mutect2, varscan2
- FDPS | c.215A>T p.N72I | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV100756286; called by muse, mutect2, varscan2
- FHOD1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV99264503; called by muse, mutect2, varscan2
- FNBP1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63090168; called by muse, mutect2, varscan2
- FOXK2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as rs941824225, COSV58878163; called by muse, mutect2, varscan2
- G3BP2 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1319713054, COSV62975821; called by muse, mutect2, varscan2
- GAL | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs762637870, COSV55763609; called by muse, mutect2, varscan2
- GALNT10 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs147745456; called by muse, mutect2, varscan2
- GCSAML | c.406T>C p.*136Qext*17 | Nonstop Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as COSV100826044; called by muse, mutect2, varscan2
- GDPD4 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60016928; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs763147690; called by mutect2, varscan2
- GPR108 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.396); catalogued as COSV99901543; called by muse, mutect2, varscan2
- GPR137C | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469415363, COSV58703913; called by muse, mutect2, varscan2
- GRINA | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as rs560551768, COSV57297391; called by muse, mutect2, varscan2
- GSPT2 | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.773); catalogued as COSV100468390, COSV61214779; called by muse, mutect2, varscan2
- H3C11 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV100138083; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 22/41 reads (54%) | catalogued as rs748396956; called by mutect2, varscan2
- HERC3 | c.777+1G>A p.X259_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99986021; called by muse, mutect2, varscan2
- HIVEP1 | c.6469C>T p.Q2157* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV101045725; called by muse, mutect2, varscan2
- HIVEP2 | c.7237A>C p.S2413R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99175434; called by muse, varscan2
- HMBOX1 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55066942; called by muse, mutect2, varscan2
- HMMR | c.1302T>A p.H434Q | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV100701053; called by muse, mutect2, varscan2
- HTR5A | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55281423; called by muse, mutect2, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 32/63 reads (51%) | catalogued as rs759151580; called by mutect2, pindel, varscan2
- IDH3G | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs782218002, COSV99473427; called by muse, mutect2, varscan2
- IGDCC3 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.93); PolyPhen benign (0.058); catalogued as rs201766054, COSV60076364; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.088); catalogued as rs1380690398; called by muse, mutect2, varscan2
- IKBKE | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100898384; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | catalogued as rs1561359523; called by mutect2, varscan2
- IPO8 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1234764565, COSV56240724; called by muse, mutect2, varscan2
- IRX1 | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV100116807; called by muse, mutect2, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- KCNJ3 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54535098; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KIAA0100 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs764531357, COSV66490321; called by muse, mutect2, varscan2
- KLC1 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as rs747324628, COSV55812394; called by muse, mutect2, varscan2
- KLK4 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as rs777659052, COSV100133555; called by muse, mutect2, varscan2
- KMT2B | c.5695C>T p.P1899S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.444); catalogued as COSV99720618; called by muse, mutect2, varscan2
- KNDC1 | c.3164G>T p.R1055L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV100466189; called by muse, mutect2, varscan2
- KRT12 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV52430096; called by muse, mutect2, varscan2
- KRT2 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100548652; called by muse, mutect2, varscan2
- LAMP5 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV55718413, COSV99855702; called by muse, mutect2, varscan2
- LILRB2 | c.1381del p.V461Lfs*2 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | catalogued as rs1278463543; called by mutect2, pindel, varscan2
- LRIG1 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370095656; called by muse, mutect2, varscan2
- LRP10 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV100612498; called by muse, mutect2, varscan2
- LRP5 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs746292760, COSV99592610; called by muse, mutect2, varscan2
- LRRC37A2 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1293431828, COSV61003665; called by mutect2, varscan2
- LRRC4C | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99539704; called by muse, mutect2, varscan2
- LTBP2 | c.4832G>A p.C1611Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100000934; called by muse, mutect2, varscan2
- LTBR | c.530A>T p.N177I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99965418; called by muse, mutect2, varscan2
- MACF1 | c.8615T>C p.I2872T | Missense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as rs779116424, COSV99246794; called by muse, mutect2, varscan2
- MAP2 | c.4420dup p.T1474Nfs*22 | Frame Shift Ins (INS) | VAF 21/49 reads (43%) | catalogued as rs1476495251; called by mutect2, varscan2
- MCM4 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.476); catalogued as rs966403056, COSV50621294; called by muse, mutect2, varscan2
- MDGA1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as rs1449487161, COSV99776398; called by muse, mutect2, varscan2
- MEDAG | c.539del p.P180Qfs*11 | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | catalogued as rs1368498416, COSV66850199; called by mutect2, pindel, varscan2
- MEFV | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs104895187, COSV54821000, COSV54826308; called by muse, mutect2, varscan2
- MEP1A | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV57920431; called by muse, mutect2, varscan2
- MGAT4B | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs1466048066, COSV99482405; called by muse, mutect2, varscan2
- MMP13 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782535983, COSV99506850; called by muse, mutect2, varscan2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs782038929; called by mutect2, pindel, varscan2
- MORC4 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55241926; called by muse, mutect2
- MPRIP | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.166); catalogued as rs757260448, COSV100506124; called by muse, mutect2, varscan2
- MS4A1 | c.159+1del | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as rs34002466, COSV61942890, COSV61943110; called by mutect2, pindel, varscan2
- MSTO1 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV99824379; called by muse, mutect2, varscan2
- MTSS2 | c.1231A>T p.S411C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV99852006; called by muse, mutect2, varscan2
- MUC4 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.494); catalogued as COSV100642220; called by muse, mutect2, varscan2
- MYF5 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs750446186, COSV57354776; called by muse, mutect2, varscan2
- MYLK4 | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV99193897; called by muse, mutect2, varscan2
- MYO1E | c.420G>A p.Q140= | Splice Region (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99896620; called by muse, mutect2, varscan2
- MYO1H | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs371876835; called by muse, mutect2, varscan2
- N4BP3 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99200817; called by muse, mutect2, varscan2
- NARS2 | c.1248G>T p.E416D | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.339); catalogued as COSV99807547; called by muse, mutect2, varscan2
- NCKAP5L | c.1809del p.S606Vfs*66 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as rs1182178199, COSV100259254, COSV60131134; called by mutect2, pindel, varscan2
- NDST3 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99631826; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | catalogued as rs747914168; called by mutect2, varscan2
- NEFL | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1364995930, COSV55337502, COSV99648177; called by muse, mutect2, varscan2
- NELL1 | c.1286_1287del p.S429Cfs*4 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as rs761021185; called by pindel, varscan2
- NEXMIF | c.4369C>A p.L1457M | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99281869; called by muse, mutect2, varscan2
- NFATC1 | c.1349C>G p.A450G | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV53695820, COSV53710046; called by muse, mutect2, varscan2
- NLRP6 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV56459777; called by muse, mutect2, varscan2
- NR4A1 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376167869; called by muse, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | catalogued as rs1167519601; called by mutect2, varscan2
- NUP35 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV99717928; called by muse, mutect2, varscan2
- NXPH3 | c.272del p.P91Hfs*6 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs915044706; called by mutect2, pindel, varscan2
- OAS3 | c.1903C>A p.L635I | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99966560; called by muse, mutect2, varscan2
- OPA1 | c.2959C>T p.R987C (on ENST00000361510 / NM_130837.3; = p.R932C on NM_015560.3) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145710079, CM091835, COSV100655477; called by muse, mutect2, varscan2
- OR4C15 | c.1049C>T p.A350V (on ENST00000314644; = p.A296V on NM_001001920.2) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as rs777527746, COSV100116094; called by muse, mutect2, varscan2
- OR9Q2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61111488; called by muse, mutect2, varscan2
- PADI1 | c.949T>A p.S317T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.307); catalogued as COSV100969272; called by muse, mutect2, varscan2
- PANK1 | c.1199dup p.P401Afs*5 (on ENST00000307534 / NM_148977.2; = p.P176Afs*5 on NM_138316.4) | Frame Shift Ins (INS) | VAF 19/45 reads (42%) | catalogued as rs1564621823; called by mutect2, varscan2
- PAPOLA | c.878G>T p.C293F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as COSV99354631; called by muse, mutect2, varscan2
- PCDHA5 | c.1841C>A p.P614H | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100972531; called by muse, mutect2, varscan2
- PCDHA7 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs782575776, COSV100971806, COSV65346027; called by muse, mutect2, varscan2
- PCDHA9 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs374903495, COSV100970087; called by muse, mutect2, varscan2
- PCDHA9 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.043); catalogued as COSV100970088; called by muse, varscan2
- PDZD2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1171348318, COSV99226664; called by muse, mutect2, varscan2
- PEAR1 | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99442330; called by muse, mutect2, varscan2
- PEAR1 | c.3012del p.G1005Afs*57 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs750264783; called by mutect2, pindel, varscan2
- PGAP4 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs549863880, COSV66388409; called by muse, mutect2, varscan2
- PKD1L1 | c.1341C>A p.N447K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99221323; called by muse, mutect2, varscan2
- PLA2G15 | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1486201576, COSV99547368; called by muse, mutect2, varscan2
- PLAU | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as rs375029894; called by muse, mutect2, varscan2
- PLEKHA4 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs200502456; called by muse, mutect2, varscan2
- PLXNB2 | c.5443G>A p.A1815T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs748967251, COSV63779930; called by muse, mutect2, varscan2
- PLXNB2 | c.3748A>G p.K1250E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV63783542; called by muse, mutect2, varscan2
- PMEL | c.1327T>C p.S443P | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100093442; called by muse, mutect2, varscan2
- PNISR | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV65080376; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as COSV100544508; called by muse, mutect2, varscan2
- POLA1 | c.3163T>C p.Y1055H | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100985780; called by muse, mutect2, varscan2
- POLR1A | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV99808406; called by muse, mutect2, varscan2
- POLR1G | c.653del p.N218Ifs*4 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs753626854; called by mutect2, varscan2
- POMT1 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1176701230, COSV61226633; called by muse, mutect2, varscan2
- POU4F2 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99850823; called by mutect2, varscan2
- PPARA | c.714T>C p.P238= | Splice Region (SNP) | VAF 21/40 reads (53%) | catalogued as COSV99415906; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 22/37 reads (59%) | catalogued as rs540232176; called by mutect2, varscan2
- PRDM5 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs750031024, COSV53368548; called by muse, mutect2, varscan2
- PRDX4 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101026765; called by muse, mutect2, varscan2
- PRPF19 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV99920767; called by muse, mutect2
- PRRC2A | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs1301413352, COSV101051369; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PSKH1 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs745836876, COSV99345015; called by muse, mutect2, varscan2
- PSMB6 | c.455dup p.M153Yfs*22 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | catalogued as rs1240803023; called by mutect2, pindel, varscan2
- PTEN | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64297260, COSV64297497; called by muse, mutect2, varscan2
- RAB11A | c.236+2T>A p.X79_splice | Splice Site (SNP) | VAF 15/28 reads (54%) | catalogued as COSV99976843; called by muse, mutect2, varscan2
- RAB24 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100293790; called by muse, varscan2
- RBM33 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV99841427; called by muse, mutect2, varscan2
- RFX7 | c.3765C>A p.D1255E (on ENST00000559447 / NM_001368074.1; = p.D1352E on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100429402; called by muse, mutect2, varscan2
- RGS21 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV101314086; called by muse, mutect2, varscan2
- RHBDL3 | c.669-1G>A p.X223_splice | Splice Site (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99283803, COSV99283959; called by muse, mutect2
- RNF17 | c.2699T>C p.V900A | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99694406; called by muse, mutect2
- SACS | c.8474G>A p.G2825D | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101207719; called by muse, mutect2, varscan2
- SCN11A | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100182523; called by muse, mutect2, varscan2
- SCN5A | c.5068G>A p.D1690N (on ENST00000333535 / NM_198056.3; = p.D1689N on NM_000335.5) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1060499900, CM136071, COSV61117100, COSV61132193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.1143del p.F381Lfs*3 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as COSV67372669; called by mutect2, pindel, varscan2
- SEMA6A | c.3036del p.K1013Nfs*11 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as rs751600344; called by mutect2, pindel, varscan2
- SERPINB1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as rs761685123, COSV66313866; called by muse, mutect2, varscan2
- SESN3 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs763498898, COSV99565984; called by muse, mutect2, varscan2
- SFI1 | c.3026C>A p.P1009Q (on ENST00000400288 / NM_001007467.3; = p.P978Q on NM_014775.4) | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99837396; called by muse, mutect2, varscan2
- SFTPA2 | c.644A>G p.E215G | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100958850; called by muse, mutect2, varscan2
- SGIP1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs200265343; called by muse, mutect2, varscan2
- SH2D3C | c.1763G>A p.R588Q (on ENST00000314830 / NM_170600.3; = p.R431Q on NM_005489.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs552881453, COSV100137539; called by muse, mutect2, varscan2
- SHROOM4 | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99174595; called by muse, mutect2, varscan2
- SIRT7 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as rs201609013, COSV100155744; called by muse, mutect2, varscan2
- SLC22A4 | c.1520del p.F507Sfs*7 | Frame Shift Del (DEL) | VAF 40/106 reads (38%) | catalogued as rs72552721; called by mutect2, pindel, varscan2
- SLC66A3 | c.436A>G p.S146G | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99706394; called by muse, mutect2
- SNRPC | c.243dup p.S82Qfs*104 | Frame Shift Ins (INS) | VAF 28/78 reads (36%) | catalogued as rs1472546666; called by mutect2, pindel, varscan2
- SNTG2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs767574929, COSV100422352, COSV100424801; called by muse, mutect2
- SNX13 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs371095846, COSV101296776; called by muse, varscan2
- SNX15 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549039083, COSV100101468; called by muse, mutect2, varscan2
- SORL1 | c.5995G>T p.G1999C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99495433; called by muse, mutect2, varscan2
- SPACA3 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs200269504, COSV52191162; called by muse, mutect2, varscan2
- SPCS3 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV101543708; called by muse, mutect2, varscan2
- SPRED1 | c.1220T>C p.L407P | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302358766, COSV100136420; called by muse, mutect2, varscan2
- SPTBN2 | c.5267C>T p.A1756V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754055406, COSV100020464; called by muse, mutect2, varscan2
- SRSF5 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs188021188, COSV99384511; called by muse, mutect2, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs753297385; called by mutect2, varscan2
- SSR4 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99473428; called by muse, mutect2, varscan2
- STAB2 | c.477C>A p.S159R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV101186297; called by muse, mutect2, varscan2
- SUZ12 | c.1363C>A p.L455M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100497085; called by muse, varscan2
- SYNM | c.2396T>C p.V799A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV100153037; called by muse, mutect2, varscan2
- SYP | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV99603147; called by muse, mutect2, varscan2
- SYT6 | c.919C>G p.L307V (on ENST00000610222 / NM_001366225.1; = p.L222V on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV101059752; called by muse, mutect2, varscan2
- SZT2 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs754481570, COSV100987653; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | catalogued as rs763321097; called by mutect2, varscan2
- TGM1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354167809, COSV99253232; called by muse, mutect2, varscan2
- THAP4 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs761728032, COSV100398318; called by muse, mutect2, varscan2
- TIAL1 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100958379; called by muse, mutect2, varscan2
- TIMM17A | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100939026; called by muse, mutect2, varscan2
- TMC4 | c.1405A>G p.N469D (on ENST00000617472 / NM_001145303.3; = p.N463D on NM_144686.4) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV99714155; called by muse, mutect2, varscan2
- TMEM82 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99606804; called by muse, mutect2
- TMEM89 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.708); catalogued as rs149964639; called by muse, mutect2, varscan2
- TMUB1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99879983; called by muse, mutect2, varscan2
- TMX4 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs376577418; called by muse, mutect2, varscan2
- TNS2 | c.2773C>T p.R925W (on ENST00000314250 / NM_170754.4; = p.R935W on NM_015319.2) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs775736487, COSV100036900; called by muse, mutect2, varscan2
- TOMM34 | c.374T>A p.I125N | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100861933; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs752676391; called by mutect2, varscan2
- TRPS1 | c.628C>T p.P210S (on ENST00000220888 / NM_001330599.2; = p.P223S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99634282; called by muse, mutect2
- TSC22D1 | c.3146del p.P1049Lfs*38 (on ENST00000458659 / NM_183422.4; = p.P120Lfs*38 on NM_006022.4) | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as rs762485832; called by mutect2, pindel, varscan2
- TTC17 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as rs1431628531, COSV99236007; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs763254614; called by mutect2, varscan2
- UBXN8 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.273); catalogued as COSV99668061; called by muse, mutect2
- UMOD | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100208689; called by muse, mutect2, varscan2
- URI1 | c.1248G>T p.E416D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100369230; called by muse, mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs762976381; called by mutect2, varscan2
- VPS26C | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs1315816013, COSV55706249; called by muse, mutect2, varscan2
- VSTM1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs908103813, COSV100618908; called by muse, mutect2, varscan2
- VWA3B | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs374632376; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR1 | c.1498G>A p.D500N (on ENST00000382452; = p.D360N on NM_005112.5) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.943); catalogued as rs762344263, COSV101221156; called by muse, mutect2, varscan2
- WDR62 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99495879; called by muse, mutect2, varscan2
- WDR7 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs201100872, COSV54351005, COSV99590410; called by muse, mutect2, varscan2
- WDR90 | c.3038del p.P1013Qfs*98 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as rs752097396; called by mutect2, pindel, varscan2
- WNK1 | c.4465T>A p.L1489I (on ENST00000315939 / NM_018979.4; = p.L1242I on NM_014823.3) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as COSV100268619; called by muse, mutect2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YIPF5 | c.319del p.T107Hfs*2 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as COSV50822908; called by mutect2, pindel
- ZBTB45 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100657794; called by muse, mutect2, varscan2
- ZDHHC9 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs1165364635, COSV64096565; called by muse, mutect2, varscan2
- ZFYVE1 | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100607117; called by muse, mutect2, varscan2
- ZIC1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99291343, COSV99292411; called by muse, mutect2, varscan2
- ZNF236 | c.3964C>T p.Q1322* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV53492582; called by muse, mutect2, varscan2
- ZNF254 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100298303; called by muse, mutect2, varscan2
- ZNF311 | c.651del p.G218Efs*11 | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | catalogued as rs758521160; called by mutect2, pindel, varscan2
- ZNF497 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs1323181181, COSV99568665; called by muse, mutect2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF696 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs1324022474, COSV100350650; called by muse, mutect2, varscan2
- ADAMTS1 | c.2791del p.R931Efs*3 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- AGO2 | c.1492del p.A498Rfs*11 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, varscan2
- ANKRD11 | c.3717del p.E1240Rfs*78 | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | called by mutect2, pindel, varscan2
- ARHGEF28 | c.2565del p.F855Lfs*3 | Frame Shift Del (DEL) | VAF 46/130 reads (35%) | called by mutect2, pindel, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 37/106 reads (35%) | called by mutect2, pindel, varscan2
- CDH7 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2
- CDK11B | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); called by muse, mutect2
- CEP152 | c.3829del p.I1277Lfs*20 (on ENST00000380950 / NM_001194998.2; = p.I1221Lfs*20 on NM_014985.4) | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | called by mutect2, varscan2
- CLIP4 | c.100del p.S34Pfs*41 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | called by mutect2, pindel, varscan2
- DYNC1LI2 | c.508dup p.M170Nfs*19 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | called by mutect2, pindel, varscan2
- EGFR | c.797del p.P266Hfs*14 | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | called by mutect2, pindel, varscan2
- FAM104A | c.268del p.Q90Rfs*48 | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | called by mutect2, pindel, varscan2
- FASN | c.4057del p.L1353Sfs*20 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- FBN3 | c.4319del p.G1440Vfs*14 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | called by mutect2, pindel, varscan2
- GAB4 | c.562del p.Q188Kfs*56 | Frame Shift Del (DEL) | VAF 29/59 reads (49%) | called by mutect2, pindel, varscan2
- GABPB1 | c.1042_1043del p.E348Sfs*8 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by pindel, varscan2
- GABRA1 | c.854_855dup p.G286Lfs*3 | Frame Shift Ins (INS) | VAF 27/50 reads (54%) | called by mutect2, pindel, varscan2
- GDF10 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2
- GGA1 | c.1404del p.S469Afs*47 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- GPHB5 | c.225del p.Y76Ifs*17 | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | called by mutect2, pindel, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 23/39 reads (59%) | called by mutect2, pindel, varscan2
- H2AC20 | c.276_278del p.E93del | In Frame Del (DEL) | VAF 33/96 reads (34%) | called by mutect2, pindel, varscan2
- HOXA11 | c.226del p.R76Afs*219 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- HSP90B1 | c.2126_2127del p.T709Sfs*10 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- HSPG2 | c.9668_9669del p.V3223Gfs*38 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by pindel, varscan2
- KCNJ14 | c.1240del p.V414Wfs*19 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- KLRK1 | c.640del p.R214Gfs*11 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, pindel, varscan2
- KRAS | c.29_31dup p.G10dup | In Frame Ins (INS) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- LAMA4 | c.788del p.P263Lfs*9 (on ENST00000230538 / NM_001105206.3; = p.P263Lfs*11 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- MEGF6 | c.3589T>C p.Y1197H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- MSANTD4 | c.544del p.H182Tfs*24 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- MUC5B | c.16417del p.A5473Pfs*129 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- MYBPHL | c.782dup p.F263Vfs*15 | Frame Shift Ins (INS) | VAF 17/39 reads (44%) | called by mutect2, pindel, varscan2
- NCOR1 | c.1914del p.G639Vfs*2 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | called by mutect2, pindel, varscan2
- NEURL4 | c.641del p.P214Lfs*62 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel
- NUCB2 | c.1200del p.K400Nfs*15 | Frame Shift Del (DEL) | VAF 27/61 reads (44%) | called by mutect2, varscan2
- OTUD7B | c.204del p.S71Lfs*81 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- PER2 | c.1025_1028del p.L342Sfs*19 | Frame Shift Del (DEL) | VAF 34/76 reads (45%) | called by pindel, varscan2
- PHF20L1 | c.1602del p.V535* | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | called by mutect2, varscan2
- PITPNM3 | c.806del p.G269Afs*100 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- PRKD2 | c.1021_1022del p.M341Gfs*2 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- RAD1 | c.164del p.N55Mfs*32 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- RAD23A | c.266del p.P89Qfs*69 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- RAG2 | c.451del p.S151Vfs*25 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- RBL1 | c.306del p.F102Lfs*4 | Frame Shift Del (DEL) | VAF 34/77 reads (44%) | called by mutect2, pindel, varscan2
- RBM34 | c.27del p.K10Rfs*97 | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- SPRING1 | c.453_456dup p.V153Sfs*16 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- TBC1D3I | c.667+1del p.X223_splice | Splice Site (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- TRGV2 | c.79A>G p.K27E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- TUBA1C | c.1236del p.M413Wfs*73 | Frame Shift Del (DEL) | VAF 50/139 reads (36%) | called by mutect2, pindel, varscan2
- UBAC1 | c.335_359del p.K112Ifs*26 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- USP6 | c.2247del p.K749Nfs*3 | Frame Shift Del (DEL) | VAF 51/164 reads (31%) | called by mutect2, pindel, varscan2
- USP9X | c.4552_4555del p.Q1518* | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | called by pindel, varscan2
- WASHC2C | c.1399dup p.H467Pfs*6 | Frame Shift Ins (INS) | VAF 70/169 reads (41%) | called by mutect2, pindel, varscan2
- ZNF516 | c.2209_2215del p.A737Rfs*19 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- ZNF831 | c.672del p.R225Dfs*37 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1620T>C p.F540= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV100229450, COSV55287900; called by muse, mutect2, varscan2
- ABHD11 | c.870G>T p.T290= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs199981712, COSV56106700, COSV99766930; called by muse, mutect2, varscan2
- ADAM8 | c.603C>T p.Y201= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs185462188, COSV69864253; called by muse, mutect2, varscan2
- AHNAK2 | c.8901C>T p.A2967= | Silent (SNP) | VAF 72/145 reads (50%) | catalogued as rs762420688, COSV100318909; called by muse, mutect2, varscan2
- AHNAK2 | c.5865G>A p.E1955= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as rs374808763; called by muse, mutect2, varscan2
- ARHGAP21 | c.5784C>T p.N1928= | Silent (SNP) | VAF 76/165 reads (46%) | catalogued as rs765097268, COSV100256650; called by muse, mutect2, varscan2
- ART1 | c.273C>T p.A91= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99167254; called by muse, mutect2
- ASCL4 | c.96G>A p.P32= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100661223; called by muse, mutect2, varscan2
- ASL | c.1290C>T p.Y430= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs780846396, CM141256, COSV59189099; called by muse, mutect2, varscan2
- BBS9 | c.2085G>A p.L695= (on ENST00000242067 / NM_001348036.1; = p.L655= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV99629982; called by muse, mutect2, varscan2
- C21orf91 | c.873G>A p.S291= (on ENST00000284881 / NM_001100420.2; = p.S290= on NM_017447.4) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs373599266, COSV99516206; called by muse, mutect2, varscan2
- C5 | c.1185T>C p.I395= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV99798705; called by muse, mutect2, varscan2
- CAPN2 | c.1191C>T p.D397= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs201268064; called by muse, mutect2, varscan2
- CDCA2 | c.2706C>T p.N902= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1167165129, COSV57946014; called by muse, mutect2, varscan2
- CEP164 | c.3702T>C p.S1234= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99634331; called by muse, mutect2, varscan2
- CFAP46 | c.6759G>T p.L2253= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99585551; called by muse, mutect2, varscan2
- CHRM3 | c.303G>A p.T101= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs200122635, COSV55100476, COSV55106765; called by muse, mutect2, varscan2
- CLN6 | c.654C>T p.G218= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99992725; called by muse, mutect2, varscan2
- CNTNAP2 | c.2070C>T p.C690= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100672534; called by muse, mutect2, varscan2
- COL6A3 | c.5457G>A p.A1819= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs377249790, COSV99799960; called by muse, mutect2, varscan2
- CRYBG2 | c.4206G>A p.T1402= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs756503684, COSV100366421, COSV57484976; called by muse, mutect2, varscan2
- CRYBG2 | c.1086C>A p.P362= | Silent (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- CSMD3 | c.1275C>G p.T425= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99827923, COSV99847330; called by muse, mutect2, varscan2
- CYP4X1 | c.993C>T p.C331= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100903364; called by muse, mutect2, varscan2
- DAAM2 | c.1995C>T p.R665= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99226984; called by muse, mutect2, varscan2
- DCC | c.75G>A p.A25= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV71426441; called by muse, mutect2, varscan2
- DDX54 | c.1101C>T p.H367= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100014195; called by muse, mutect2, varscan2
- DHX37 | c.2796C>A p.G932= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100439488; called by muse, mutect2, varscan2
- DISP1 | c.3600C>T p.H1200= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99452169; called by muse, varscan2
- DNAH2 | c.8643C>T p.R2881= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs369284368; called by muse, mutect2, varscan2
- DNAJC11 | c.1392C>T p.I464= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs148060356; called by muse, mutect2, varscan2
- DPEP3 | c.96C>T p.P32= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1425325280, COSV99262562; called by muse, mutect2, varscan2
- DTYMK | c.294C>T p.Y98= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1011116139, COSV99994789; called by muse, mutect2, varscan2
- DYRK2 | c.720C>T p.Y240= (on ENST00000344096 / NM_006482.3; = p.Y167= on NM_003583.4) | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs376046839; called by muse, varscan2
- DYSF | c.4767C>T p.G1589= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs1211089520; called by muse, mutect2
- EFCAB11 | c.486A>G p.E162= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV100369188; called by muse, mutect2, varscan2
- EMP2 | c.417C>T p.Y139= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs781680281, COSV100852882; called by muse, mutect2, varscan2
- FBXL18 | c.1086G>A p.L362= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV101212114; called by muse, mutect2, varscan2
- FBXW10 | c.1369C>A p.R457= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100111759; called by muse, mutect2, varscan2
- FGF6 | c.186C>T p.R62= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs202212518, COSV57403376; called by muse, mutect2, varscan2
- FLI1 | c.882C>T p.S294= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1448246958, COSV55643944; called by muse, mutect2, varscan2
- FOSL1 | c.708C>T p.T236= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV100440983; called by muse, mutect2, varscan2
- GALNT16 | c.429G>A p.V143= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100546174; called by muse, mutect2, varscan2
- GLI3 | c.2028G>A p.Q676= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101230038; called by muse, mutect2, varscan2
- GOLGA6A | c.1434A>G p.L478= | Silent (SNP) | VAF 46/171 reads (27%) | catalogued as COSV99297377; called by muse, mutect2
- GPRC5A | c.249C>T p.F83= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs148167346; called by muse, mutect2, varscan2
- GRID2 | c.1983T>C p.I661= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99946737; called by muse, mutect2, varscan2
- GULP1 | c.897G>A p.P299= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs759462867, COSV63073309; called by muse, mutect2, varscan2
- HCFC1 | c.4560G>A p.L1520= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100129860; called by muse, mutect2, varscan2
- HCN3 | c.126T>C p.P42= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100751926; called by muse, mutect2, varscan2
- HINFP | c.510G>A p.L170= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100640888; called by muse, mutect2, varscan2
- HMGCLL1 | c.12G>A p.V4= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99233188; called by muse, mutect2, varscan2
- HS3ST1 | c.183C>T p.G61= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs1483731616, COSV50025036, COSV50027825; called by muse, mutect2, varscan2
- IDH2 | c.141G>A p.A47= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs145802942; called by muse, mutect2, varscan2
- ITGAM | c.1371C>T p.F457= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs774447380, COSV54935390; called by muse, mutect2, varscan2
- KCTD9 | c.33C>T p.S11= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs558313972, COSV99648833; called by muse, varscan2
- KDM3B | c.2569C>T p.L857= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100070221; called by muse, mutect2, varscan2
- KDM6A | c.1677T>C p.R559= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100938571; called by muse, mutect2, varscan2
- KL | c.2454A>G p.K818= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV101199198; called by muse, mutect2, varscan2
- KRTAP19-1 | c.159C>T p.Y53= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs201530613, COSV66861452, COSV66861701; called by muse, mutect2, varscan2
- LCN1 | c.183C>A p.T61= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99704544; called by muse, mutect2, varscan2
- LRP1B | c.11347C>A p.R3783= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV101260873, COSV67219306; called by muse, mutect2, varscan2
- LSR | c.489C>T p.Y163= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs772482143, COSV61555195; called by muse, mutect2
- LTB | c.351G>A p.T117= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV101438068; called by muse, mutect2, varscan2
- MAP1B | c.3522C>T p.Y1174= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV57105716; called by muse, mutect2, varscan2
- MBNL2 | c.567C>T p.N189= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100600546; called by muse, mutect2, varscan2
- MKI67 | c.5916C>T p.T1972= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs753327136, COSV64074869; called by muse, mutect2, varscan2
- MMD2 | c.195G>A p.E65= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV101287141; called by mutect2, varscan2
- MMP13 | c.477C>A p.G159= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99506854; called by muse, mutect2, varscan2
- MMP9 | c.2088C>T p.Y696= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs369032528; ClinVar: likely benign; called by muse, mutect2
- MPHOSPH9 | c.735T>C p.N245= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV100187197; called by muse, mutect2, varscan2
- MYH1 | c.3846G>A p.A1282= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs371584505; called by muse, mutect2, varscan2
- MYH14 | c.1614C>T p.I538= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as COSV99224102; called by muse, mutect2, varscan2
- NCF4 | c.888G>A p.R296= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1225641160, COSV99957542; called by muse, mutect2, varscan2
- NCOA6 | c.5142G>A p.P1714= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs754728574, COSV100750347; called by muse, mutect2, varscan2
- NIBAN3 | c.129G>A p.Q43= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs990685600, COSV99962717; called by muse, mutect2, varscan2
- NIP7 | c.480G>A p.A160= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs1158286356, COSV54741711; called by muse, mutect2, varscan2
- NXF3 | c.1440C>T p.G480= | Silent (SNP) | VAF 134/297 reads (45%) | catalogued as COSV101222080; called by muse, mutect2, varscan2
- OPRL1 | c.909C>T p.F303= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100402277; called by muse, mutect2, varscan2
- OR56A3 | c.888C>T p.Y296= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs755632245, COSV61569824; called by muse, mutect2, varscan2
- PCDH9 | c.300C>T p.G100= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs766591580, COSV60560327; called by muse, mutect2, varscan2
- PCDHA6 | c.1146C>T p.N382= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as rs782289656, COSV67062352; called by muse, mutect2, varscan2
- PCDHA6 | c.1611G>A p.A537= | Silent (SNP) | VAF 69/144 reads (48%) | catalogued as rs1295697160, COSV65344249; called by muse, mutect2, varscan2
- PCDHA7 | c.1650G>A p.T550= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as COSV65345984; called by muse, mutect2, varscan2
- PCDHB9 | c.1341C>T p.N447= | Silent (SNP) | VAF 64/129 reads (50%) | catalogued as rs1459171550, COSV53376231; called by muse, mutect2, varscan2
- PCDHGA1 | c.67C>T p.L23= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV100966085; called by muse, varscan2
- PDK4 | c.948G>T p.T316= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV99138973; called by muse, mutect2, varscan2
- PEAK1 | c.4170C>T p.D1390= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100433433, COSV56930871; called by muse, mutect2, varscan2
- PLA2G4F | c.745C>T p.L249= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV101215367; called by muse, mutect2
- PPEF2 | c.495G>A p.R165= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV54423058, COSV99714987; called by muse, mutect2, varscan2
- PPP5C | c.534A>G p.G178= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99183691; called by muse, mutect2, varscan2
- PRAMEF14 | c.1197C>T p.C399= | Silent (SNP) | VAF 114/228 reads (50%) | catalogued as COSV100577305; called by muse, mutect2, varscan2
- RBM6 | c.360A>T p.I120= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV99805900; called by muse, mutect2, varscan2
- RBP3 | c.2022C>T p.R674= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- RCC1 | c.1218C>T p.S406= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs779103379, COSV100868194; called by muse, mutect2, varscan2
- RET | c.750C>A p.R250= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs1013952995, CD1211876, COSV100394538; called by muse, mutect2, varscan2
- RGS3 | c.393G>A p.T131= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs745805685, COSV58280299; called by muse, mutect2, varscan2
- RIC8B | c.1368C>G p.G456= | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as COSV100822731; called by muse, mutect2, varscan2
- RINT1 | c.1386G>A p.S462= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as rs763396368, COSV57558957; called by muse, mutect2, varscan2
- RNASEL | c.2124G>A p.Q708= | Silent (SNP) | VAF 59/140 reads (42%) | catalogued as COSV100842648; called by muse, mutect2, varscan2
- RNASEL | c.1800A>G p.G600= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as COSV100842649; called by muse, mutect2, varscan2
- RNF213 | c.14691C>A p.A4897= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100301474, COSV60390411; called by muse, mutect2, varscan2
- RNF26 | c.966C>A p.T322= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100264929; called by muse, mutect2, varscan2
- RPN1 | c.1800C>T p.I600= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs142951968; called by muse, mutect2
- RPS6KA2 | c.1143A>G p.S381= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99692085; called by muse, mutect2, varscan2
- RREB1 | c.4824C>T p.A1608= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100619842; called by muse, mutect2, varscan2
- RUBCNL | c.1830G>A p.T610= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs767364076, COSV100529375; called by muse, mutect2, varscan2
- SCN4A | c.1959C>T p.S653= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1026905066, COSV101438652; called by muse, mutect2, varscan2
- SDF4 | c.168C>T p.N56= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as rs374721191; called by muse, mutect2, varscan2
- SERPINA3 | c.279T>C p.N93= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV101261818; called by muse, mutect2, varscan2
- SH3PXD2A | c.1506C>T p.I502= (on ENST00000369774 / NM_001365079.1; = p.I474= on NM_014631.2) | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs748216122, COSV100280077; called by muse, mutect2, varscan2
- SRSF4 | c.222G>A p.R74= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs1383797586, COSV100861437; called by muse, mutect2
- STAB1 | c.162G>A p.T54= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs148585452; called by muse, mutect2, varscan2
- STRN | c.1734T>C p.S578= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99815705; called by muse, mutect2, varscan2
- SVOPL | c.1287T>A p.A429= (on ENST00000419765; = p.A277= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99939641; called by muse, mutect2, varscan2
- TAB1 | c.1212C>T p.S404= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs539182225, COSV53371165; called by muse, mutect2, varscan2
- TAF1 | c.3792A>G p.Q1264= (on ENST00000373790 / NM_138923.4; = p.Q1285= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV52117251; called by muse, mutect2, varscan2
- TASOR2 | c.3138G>A p.V1046= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100051017; called by muse, mutect2, varscan2
- TCEA2 | c.360G>A p.P120= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs758030338, COSV100180900; called by muse, mutect2, varscan2
- TGOLN2 | c.1080G>A p.S360= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as COSV99965126; called by muse, mutect2, varscan2
- TMEM14B | c.105C>T p.S35= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs146042312; called by muse, mutect2, varscan2
- TNN | c.2148C>T p.T716= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs745346359, COSV99512975; called by muse, mutect2, varscan2
- TRIL | c.2355C>T p.D785= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1490047476, COSV100538975; called by muse, mutect2, varscan2
- TSPAN6 | c.18G>T p.R6= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV100885937; called by muse, mutect2, varscan2
- UNC93B1 | c.1452C>T p.T484= | Silent (SNP) | VAF 70/174 reads (40%) | catalogued as rs762916919, COSV99916522; called by muse, mutect2, varscan2
- UPB1 | c.9C>T p.G3= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs201559029, COSV58116778; called by muse, mutect2, varscan2
- USP11 | c.1350C>T p.N450= (on ENST00000218348; = p.N407= on NM_001371072.1) | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs371126083, COSV99511170; called by muse, mutect2, varscan2
- UTP20 | c.4338C>T p.F1446= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs780212979, COSV55373777; called by muse, mutect2, varscan2
- VNN2 | c.1206C>T p.C402= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1423160747, COSV100426943; called by muse, mutect2, varscan2
- VPS13B | c.5661C>T p.P1887= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100663580; called by muse, mutect2
- WNK2 | c.5037G>A p.S1679= (on ENST00000297954 / NM_001282394.1; = p.S1642= on NM_006648.3) | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs567234521, COSV99944542; called by muse, varscan2
- XAB2 | c.88C>A p.R30= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs779853299, COSV100222116; called by muse, mutect2, varscan2
- YWHAQ | c.399G>A p.A133= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs773284973, COSV53002574, COSV99431458; called by muse, mutect2, varscan2
- ZBTB40 | c.1404C>G p.R468= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV100989103; called by muse, mutect2, varscan2
- ZDHHC18 | c.465C>T p.V155= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100938875; called by muse, mutect2
- ZFP14 | c.1575G>A p.Q525= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV99525323; called by muse, mutect2, varscan2
- ZNF142 | c.2610C>T p.G870= (on ENST00000411696 / NM_001379660.1; = p.G670= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV101376999; called by muse, mutect2, varscan2
- ZNF182 | c.804A>G p.G268= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100527212; called by muse, mutect2, varscan2
- ZNF292 | c.144C>T p.T48= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1370814600, COSV100371240; called by muse, mutect2
- ZNF43 | c.1314C>A p.P438= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100731966, COSV61684821; called by muse, mutect2, varscan2
- ZNF548 | c.94C>T p.L32= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as COSV100278290; called by muse, mutect2, varscan2
- ZNF862 | c.1578G>A p.R526= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1356954192, COSV99783807; called by muse, mutect2, varscan2
- ZSCAN18 | c.1411C>T p.L471= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs1403753401, COSV99559708; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-926G>A | Intron (SNP) | VAF 16/34 reads (47%) | catalogued as rs41306564, COSV60824617; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848662 C>T | 5'Flank (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852081 G>A | 3'Flank (SNP) | VAF 13/43 reads (30%) | catalogued as rs1279307161; called by muse, mutect2, varscan2
- AMACR | c.739+1181G>A | Intron (SNP) | VAF 28/58 reads (48%) | catalogued as COSV100163253; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501569 ins T | 5'Flank (INS) | VAF 24/41 reads (59%) | called by mutect2, varscan2
- CEP295 | c.5851-193del | Intron (DEL) | VAF 35/66 reads (53%) | catalogued as rs754124024; called by mutect2, pindel, varscan2
- COPS9 | chr2:240126868 del C | 3'Flank (DEL) | VAF 15/40 reads (38%) | catalogued as COSV56228819; called by mutect2, pindel, varscan2
- HTR2C | c.350-24471G>A | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99348486, COSV99350959; called by muse, mutect2, varscan2
- MIR129-2 | n.10C>T | RNA (SNP) | VAF 31/52 reads (60%) | called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21172393 A>G | 5'Flank (SNP) | VAF 20/42 reads (48%) | catalogued as COSV101346362; called by muse, mutect2, varscan2
- NXF5 | n.984G>A | RNA (SNP) | VAF 37/112 reads (33%) | catalogued as COSV99534659; called by muse, mutect2, varscan2
- PCDHGA1 | chr5:141330683 C>T | 5'Flank (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100966083; called by muse, varscan2
- RBAK | c.-145G>A | 5'UTR (SNP) | VAF 33/83 reads (40%) | catalogued as rs1446559356, COSV100806773; called by muse, mutect2, varscan2
- SSPOP | n.3490G>T | RNA (SNP) | VAF 20/65 reads (31%) | catalogued as COSV50487767, COSV50488656; called by muse, mutect2, varscan2
- SSPOP | n.8581del | RNA (DEL) | VAF 19/52 reads (37%) | catalogued as rs552397911; called by mutect2, pindel, varscan2
